Somatic mutation profile of tumor specimen ALCH-B43V-TTP1-A (aliquot ALCH-B43V-TTP1-A-1-0-D-A80E-36) from ALCHEMIST case ALCH-B43V, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 50.7 years (18,524 days).
Specimen ALCH-B43V-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fb9f66f2-a56e-4e2e-a81d-14966c7130fb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B43V-NB1-A (Blood Derived Normal), aliquot ALCH-B43V-NB1-A-1-0-D-A80E-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cf4e69b4-33aa-492c-a967-1f9dfffe09b9

The open-access MAF lists 59 somatic variants for this specimen: 42 protein-altering or splice-affecting, 11 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 11, Intron 5, Nonsense Mutation 4, Frame Shift Del 2, Splice Site 2, In Frame Del 1, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 774/1112 reads (70%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.499C>T p.Q167* | Nonsense Mutation (SNP) | VAF 32/139 reads (23%) | hotspot (GDC flag); catalogued as rs1555526097, CM942118, COSV52735517, COSV53025177, COSV53136193, COSV53312374; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CADM2 | c.397del p.S133Hfs*9 (on ENST00000407528 / NM_001167674.2; = p.S135Hfs*9 on NM_153184.4) | Frame Shift Del (DEL) | VAF 15/137 reads (11%) | catalogued as COSV101052666; called by mutect2, pindel, varscan2
- CAPN2 | c.1051G>A p.D351N | Missense Mutation (SNP) | VAF 29/265 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.363); catalogued as rs149659079; called by muse, mutect2
- CCT6B | c.513T>G p.V171= | Splice Region (SNP) | VAF 11/154 reads (7%) | catalogued as rs201200052; called by muse, mutect2
- CDH5 | c.1894G>A p.G632S | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0.067); catalogued as rs759015093; called by muse, mutect2, varscan2
- GLT6D1 | c.670G>A p.D224N | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV65628015; called by muse, mutect2, varscan2
- GRM1 | c.832C>T p.R278* | Nonsense Mutation (SNP) | VAF 30/544 reads (6%) | catalogued as COSV51132803, COSV51271244; called by muse, mutect2
- LARS1 | c.1656-1G>T p.X552_splice (on ENST00000394434 / NM_020117.11; = p.X525_splice on NM_016460.3) | Splice Site (SNP) | VAF 12/140 reads (9%) | catalogued as rs1321072882; called by muse, mutect2
- MAGI2 | c.2485G>C p.D829H | Missense Mutation (SNP) | VAF 12/287 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62674287; called by muse, mutect2
- MED12L | c.4106A>G p.D1369G | Missense Mutation (SNP) | VAF 12/214 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.438); catalogued as rs1247573278; called by muse, mutect2
- MLNR | c.736C>T p.R246C | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.939); catalogued as rs761691235; called by muse, mutect2, varscan2
- PCDHA3 | c.1671C>A p.D557E | Missense Mutation (SNP) | VAF 42/481 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs199682432, COSV63539775; called by muse, mutect2
- PHKG1 | c.202C>T p.R68* | Nonsense Mutation (SNP) | VAF 22/385 reads (6%) | catalogued as rs137913814, COSV52079575, COSV99818338; called by muse, mutect2
- RUNX1T1 | c.1264G>C p.D422H (on ENST00000265814 / NM_001198628.1; = p.D395H on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/475 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as COSV56142543; called by muse, mutect2
- WDR74 | c.652C>T p.R218W | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375498274; called by muse, varscan2
- XK | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 7/132 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66120078; called by muse, mutect2
- ZNF836 | c.2617C>T p.R873W | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.972); catalogued as rs750525227, COSV59081627; called by muse, mutect2
- APC | c.1485_1487del p.T496del | In Frame Del (DEL) | VAF 51/356 reads (14%) | called by mutect2, pindel, varscan2
- ARHGEF6 | c.394C>T p.Q132* | Nonsense Mutation (SNP) | VAF 22/442 reads (5%) | called by muse, mutect2
- CST2 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 27/173 reads (16%) | SIFT tolerated (0.93); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ELMO1 | c.1930A>T p.I644F | Missense Mutation (SNP) | VAF 69/271 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.302); called by muse, mutect2, varscan2
- GLT6D1 | c.490G>A p.D164N | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0.194); called by muse, mutect2
- KIR2DL3 | c.986A>G p.D329G | Missense Mutation (SNP) | VAF 61/403 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- LRP1B | c.5111G>T p.R1704M | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.707); called by muse, mutect2
- MED1 | c.1743C>A p.S581R | Missense Mutation (SNP) | VAF 11/254 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.014); called by muse, mutect2
- MYB | c.1488A>T p.E496D | Missense Mutation (SNP) | VAF 11/138 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.953); called by muse, mutect2
- NCOA4 | c.530C>T p.P177L | Missense Mutation (SNP) | VAF 34/263 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.274); called by muse, mutect2, varscan2
- OSER1 | c.746C>T p.S249F | Missense Mutation (SNP) | VAF 27/236 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); called by muse, mutect2, varscan2
- PLCB1 | c.3456C>A p.D1152E | Missense Mutation (SNP) | VAF 18/226 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2
- PLCB4 | c.369+2T>C p.X123_splice | Splice Site (SNP) | VAF 16/107 reads (15%) | called by muse, mutect2
- POLH | c.201T>G p.D67E | Missense Mutation (SNP) | VAF 36/564 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0.013); called by muse, mutect2
- RASAL3 | c.50C>T p.T17I | Missense Mutation (SNP) | VAF 19/191 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2
- RGS3 | c.1503G>T p.K501N (on ENST00000350696 / NM_001282923.2; = p.K389N on NM_017790.4) | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- SEC31B | c.2577del p.N860Ifs*2 | Frame Shift Del (DEL) | VAF 12/112 reads (11%) | called by mutect2, pindel, varscan2
- SGCD | c.457A>T p.N153Y (on ENST00000435422 / NM_001128209.2; = p.N154Y on NM_000337.5) | Missense Mutation (SNP) | VAF 42/231 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- SLC22A9 | c.106A>G p.M36V | Missense Mutation (SNP) | VAF 43/439 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2
- TNKS1BP1 | c.2012C>T p.A671V | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2
- TNN | c.1814G>A p.G605E | Missense Mutation (SNP) | VAF 17/221 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); called by muse, mutect2
- WWP1 | c.1517A>G p.Y506C | Missense Mutation (SNP) | VAF 24/219 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- ZBTB4 | c.1805G>T p.C602F | Missense Mutation (SNP) | VAF 17/156 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- ZNF184 | c.2099G>T p.C700F | Missense Mutation (SNP) | VAF 14/177 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CYP4B1 | c.936C>T p.F312= | Silent (SNP) | VAF 18/209 reads (9%) | called by muse, mutect2
- FBXO47 | c.645C>T p.I215= | Silent (SNP) | VAF 13/114 reads (11%) | called by muse, mutect2, varscan2
- GRIN2B | c.1875G>A p.G625= | Silent (SNP) | VAF 67/599 reads (11%) | catalogued as COSV74207180; called by muse, mutect2, varscan2
- HACD1 | c.594T>C p.I198= | Silent (SNP) | VAF 9/103 reads (9%) | called by muse, mutect2
- MTMR3 | c.2379G>C p.V793= | Silent (SNP) | VAF 11/126 reads (9%) | called by muse, mutect2
- MYH1 | c.51C>A p.L17= | Silent (SNP) | VAF 17/383 reads (4%) | called by muse, mutect2
- NRXN1 | c.453C>T p.S151= | Silent (SNP) | VAF 41/221 reads (19%) | catalogued as rs774821523, COSV68007971, COSV68052403; called by muse, mutect2, varscan2
- OR52N1 | c.501C>T p.R167= | Silent (SNP) | VAF 28/248 reads (11%) | catalogued as rs752620306; called by muse, mutect2, varscan2
- OXTR | c.1131C>T p.S377= | Silent (SNP) | VAF 4/88 reads (5%) | called by muse, mutect2
- PTPRN | c.630G>T p.L210= | Silent (SNP) | VAF 16/179 reads (9%) | called by muse, mutect2
- SLC7A4 | c.1167G>A p.S389= | Silent (SNP) | VAF 22/181 reads (12%) | catalogued as rs376315602; called by muse, mutect2, varscan2
- CALU | c.415+196A>C | Intron (SNP) | VAF 17/192 reads (9%) | called by muse, mutect2
- IGFN1 | c.1242-2396G>C | Intron (SNP) | VAF 22/442 reads (5%) | called by muse, mutect2
- ISL1 | c.219-870T>G | Intron (SNP) | VAF 16/334 reads (5%) | called by muse, mutect2
- RASGRF1 | c.3542+1600A>T | Intron (SNP) | VAF 6/43 reads (14%) | called by muse, mutect2, varscan2
- TFRC | c.1468+56A>T | Intron (SNP) | VAF 10/87 reads (11%) | called by muse, mutect2, varscan2
- UBBP4 | n.677G>C | RNA (SNP) | VAF 18/344 reads (5%) | called by muse, mutect2
